Somatic mutation profile of tumor specimen ALCH-B2BY-TTP1-A (aliquot ALCH-B2BY-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2BY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.2 years (20,176 days).
Specimen ALCH-B2BY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5eb1b30-8663-4877-b7db-f1c18fa2ce1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2BY-NB3-A (Blood Derived Normal), aliquot ALCH-B2BY-NB3-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b905081-2b3c-4236-ad58-e39560eac58a

The open-access MAF lists 104 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 23, Intron 7, Nonsense Mutation 5, 5'UTR 2, 3'UTR 2, Splice Region 2, RNA 2, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 326/965 reads (34%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ABCC8 | c.4252C>T p.R1418C | Missense Mutation (SNP) | VAF 56/652 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468762603, CM107095; called by muse, mutect2
- ACVR2A | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 76/334 reads (23%) | catalogued as COSV99065820; called by muse, mutect2, varscan2
- ATP5MC2 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 135/537 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100101000; called by muse, mutect2, varscan2
- CCDC130 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 23/446 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.067); catalogued as rs1333567004, COSV99681343; called by muse, mutect2
- CCDC151 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs748442231, COSV62697369; called by muse, mutect2, varscan2
- CENPV | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.605); catalogued as rs1281248889; called by muse, mutect2, varscan2
- COL26A1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746391883, COSV58125966; called by muse, mutect2, varscan2
- COL6A1 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 28/317 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1242204124; called by muse, mutect2
- DCUN1D2 | c.264G>C p.Q88H | Missense Mutation (SNP) | VAF 133/549 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.47); catalogued as rs1566504483, COSV60262360; called by muse, mutect2, varscan2
- GLUL | c.330G>C p.E110D | Missense Mutation (SNP) | VAF 58/632 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs928667656; called by muse, mutect2
- HCN1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 91/695 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100302595, COSV57514751, COSV57516637; called by muse, mutect2, varscan2
- HELB | c.2128C>T p.Q710* | Nonsense Mutation (SNP) | VAF 48/411 reads (12%) | catalogued as rs138227394; called by muse, mutect2, varscan2
- HSFX4 | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.51); catalogued as COSV62207290; called by muse, mutect2, varscan2
- IQCN | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs375163242; called by muse, mutect2
- IRAK3 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as rs1438019075; called by muse, mutect2, varscan2
- KIF5A | c.2088+3G>A | Splice Region (SNP) | VAF 97/650 reads (15%) | catalogued as rs745342702; called by muse, mutect2, varscan2
- LLGL2 | c.2954-7C>A | Splice Region (SNP) | VAF 37/149 reads (25%) | catalogued as rs1004214031; called by muse, mutect2, varscan2
- MAGOHB | c.21C>G p.F7L | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV57898141; called by muse, mutect2
- MED23 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 148/603 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV63432701; called by muse, mutect2, varscan2
- MFSD4A | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 199/550 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.076); catalogued as rs770289370; called by mutect2, varscan2
- MMP26 | c.744C>G p.I248M | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56172364; called by muse, mutect2, varscan2
- NDST4 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 28/288 reads (10%) | catalogued as rs746389915, COSV52121596; called by muse, mutect2, varscan2
- NOA1 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | catalogued as COSV51736958; called by muse, mutect2, varscan2
- PASK | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 173/451 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs753013231; called by muse, mutect2, varscan2
- PLG | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 24/775 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as COSV51983222; called by muse, mutect2
- POMC | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs757423347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGSL1 | c.3110C>A p.A1037E | Missense Mutation (SNP) | VAF 82/371 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.188); catalogued as rs1331793753; called by muse, mutect2, varscan2
- RPS25 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV57723156; called by muse, mutect2, varscan2
- SEMA3B | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782038714; called by muse, mutect2, varscan2
- STX1A | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as COSV56095953; called by muse, mutect2, varscan2
- TBC1D4 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.928); catalogued as COSV66489917; called by muse, mutect2, varscan2
- USH2A | c.14011G>A p.E4671K | Missense Mutation (SNP) | VAF 46/518 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs769560933, COSV56326302; called by muse, mutect2
- ACVR2B | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 175/435 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHCTF1 | c.6531A>T p.E2177D (on ENST00000366508; = p.E2151D on NM_015446.5) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AKR1C3 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ARHGAP23 | c.2021A>T p.K674M | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- BPIFB4 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 20/641 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- BRWD3 | c.1923C>A p.D641E | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.062); called by muse, mutect2
- CAMSAP2 | c.2978A>C p.E993A (on ENST00000236925 / NM_001297707.2; = p.E982A on NM_203459.3) | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- CCNT2 | c.1605_1606del p.H535Qfs*4 | Frame Shift Del (DEL) | VAF 50/262 reads (19%) | called by pindel, varscan2
- COL4A1 | c.2753G>A p.G918E | Missense Mutation (SNP) | VAF 24/661 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD1 | c.3953G>C p.S1318T (on ENST00000520002; = p.S1317T on NM_033225.6) | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, varscan2
- DBX2 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DENND5A | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 184/573 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- DNTTIP1 | c.673A>T p.M225L | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXO4 | c.1244G>T p.C415F | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HYKK | c.483C>A p.F161L | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- IRF6 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 133/557 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LILRA2 | c.1442C>A p.A481D (on ENST00000391738 / NM_001130917.3; = p.A464D on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MMUT | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 49/584 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MUC5B | c.16159G>T p.G5387W | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- NAV3 | c.5624C>T p.S1875F (on ENST00000397909 / NM_001024383.2; = p.S1853F on NM_014903.6) | Missense Mutation (SNP) | VAF 118/476 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NCR3LG1 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 125/475 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PLPPR3 | c.1400C>T p.S467L (on ENST00000520876 / NM_001270366.2; = p.S495L on NM_024888.2) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- RIN3 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA3C | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SFMBT2 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 162/543 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SFRP5 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 80/264 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SGMS1 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 118/407 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SLC19A2 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- STOX2 | c.1702A>T p.S568C | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX51 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 75/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM231 | c.86T>A p.L29Q (on ENST00000258173 / NM_001077418.3; = p.W26R on NM_001077416.2) | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TNRC18 | c.3789G>C p.E1263D | Missense Mutation (SNP) | VAF 42/450 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); called by muse, mutect2
- ZNF133 | c.1720G>A p.E574K (on ENST00000316358 / NM_001352454.2; = p.E573K on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/243 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.439); called by muse, mutect2
- ZNF433 | c.147dup p.W50Mfs*26 | Frame Shift Ins (INS) | VAF 43/222 reads (19%) | called by mutect2, pindel, varscan2
- ZNF541 | c.2917C>G p.R973G | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- AKR1C1 | c.660A>T p.G220= | Silent (SNP) | VAF 15/414 reads (4%) | called by muse, mutect2
- ANK2 | c.7599G>A p.K2533= | Silent (SNP) | VAF 35/229 reads (15%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2943G>A p.L981= | Silent (SNP) | VAF 82/272 reads (30%) | called by muse, mutect2, varscan2
- ASPM | c.18G>T p.V6= | Silent (SNP) | VAF 14/243 reads (6%) | called by muse, mutect2
- ATP2A2 | c.252A>T p.T84= | Silent (SNP) | VAF 206/662 reads (31%) | called by muse, mutect2, varscan2
- C1orf43 | c.415C>T p.L139= (on ENST00000368521 / NM_001297718.2; = p.L105= on NM_015449.4) | Silent (SNP) | VAF 52/700 reads (7%) | called by muse, mutect2
- CEP250 | c.4861C>T p.L1621= | Silent (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- FGF18 | c.423G>T p.L141= | Silent (SNP) | VAF 33/300 reads (11%) | catalogued as rs754506505; called by muse, mutect2, varscan2
- GCA | c.330A>T p.G110= | Silent (SNP) | VAF 49/184 reads (27%) | called by muse, mutect2, varscan2
- GPCPD1 | c.1206T>C p.F402= | Silent (SNP) | VAF 40/183 reads (22%) | called by muse, varscan2
- HIF1AN | c.18G>C p.A6= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- LAMA4 | c.648C>T p.T216= | Silent (SNP) | VAF 105/337 reads (31%) | called by muse, mutect2, varscan2
- MARCHF11 | c.306C>A p.S102= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- MARCHF4 | c.750C>T p.A250= | Silent (SNP) | VAF 10/286 reads (3%) | called by muse, mutect2
- PCDHA5 | c.1572C>T p.H524= | Silent (SNP) | VAF 20/674 reads (3%) | called by muse, mutect2
- PCDHB12 | c.1530C>T p.N510= | Silent (SNP) | VAF 170/635 reads (27%) | catalogued as rs1554286944, COSV53394324, COSV99507721; called by muse, mutect2, varscan2
- STPG2 | c.1128T>C p.S376= | Silent (SNP) | VAF 100/396 reads (25%) | called by muse, mutect2, varscan2
- TAOK2 | c.1476G>C p.L492= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- TCAIM | c.930G>C p.L310= | Silent (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
- ZNF329 | c.57A>T p.V19= | Silent (SNP) | VAF 32/111 reads (29%) | called by mutect2, varscan2
- ZNF469 | c.2451G>A p.L817= | Silent (SNP) | VAF 84/340 reads (25%) | catalogued as rs1453325537; called by muse, mutect2, varscan2
- ZNF536 | c.318C>G p.L106= | Silent (SNP) | VAF 50/428 reads (12%) | called by muse, mutect2
- ZSCAN12 | c.1092C>T p.G364= | Silent (SNP) | VAF 41/284 reads (14%) | called by muse, mutect2, varscan2
- ADD1 | c.1605+758G>A | Intron (SNP) | VAF 122/439 reads (28%) | catalogued as rs570770774; called by muse, mutect2, varscan2
- ARPC3 | c.*237G>C | 3'UTR (SNP) | VAF 7/192 reads (4%) | called by muse, mutect2
- C5orf64 | n.512+8362A>G | Intron (SNP) | VAF 109/403 reads (27%) | called by muse, mutect2, varscan2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 18/240 reads (8%) | catalogued as rs1291738365; called by muse, mutect2
- CPA2 | c.486+591G>A | Intron (SNP) | VAF 76/162 reads (47%) | catalogued as rs747461372; called by muse, varscan2
- CTAGE11P | n.297A>T | RNA (SNP) | VAF 36/1100 reads (3%) | called by muse, mutect2
- CTAGE11P | n.296G>A | RNA (SNP) | VAF 37/1085 reads (3%) | catalogued as rs1366017771; called by muse, mutect2
- DENND1A | c.1578-3876G>A | Intron (SNP) | VAF 16/404 reads (4%) | called by muse, mutect2
- IGKV1D-17 | c.-1C>G | 5'UTR (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- IL13RA1 | c.1010-3411G>A | Intron (SNP) | VAF 26/79 reads (33%) | catalogued as rs772391436; called by muse, mutect2, varscan2
- IVD | c.243+13G>T | Intron (SNP) | VAF 46/152 reads (30%) | called by mutect2, varscan2
- NPR3 | c.*3272C>A | 3'UTR (SNP) | VAF 52/447 reads (12%) | called by muse, mutect2, varscan2
- VPS29 | c.-60G>A | 5'UTR (SNP) | VAF 26/378 reads (7%) | called by muse, mutect2
